Somatic mutation profile of tumor specimen C3L-00422-01 (aliquot CPT0082850010) from CPTAC case C3L-00422, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 35.2 years (12,844 days).
Specimen C3L-00422-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0afbaaa7-54f4-4c45-b11d-88c0c05bb6d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00422-31 (Blood Derived Normal), aliquot CPT0081740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f35e32a4-4f76-4205-84dd-b5dac8aee10d

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Del 2, 3'UTR 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATL1 | c.1186del p.E396Kfs*4 | Frame Shift Del (DEL) | VAF 15/131 reads (11%) | catalogued as COSV100613164; called by mutect2, pindel, varscan2
- ATP2A1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 207/647 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.03); catalogued as rs764921561; called by muse, mutect2, varscan2
- F5 | c.4622T>C p.I1541T | Missense Mutation (SNP) | VAF 92/163 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs901676018; called by muse, mutect2, varscan2
- FNBP4 | c.422T>A p.I141N | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55452363; called by muse, mutect2, varscan2
- HLX | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as rs759920876; called by muse, mutect2, varscan2
- MGA | c.1704T>G p.D568E | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAPGEF4 | c.200del p.G67Efs*2 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- SVEP1 | c.8814T>G p.D2938E | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- PANX2 | c.396C>T p.A132= | Silent (SNP) | VAF 35/130 reads (27%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1039-4269G>A | Intron (SNP) | VAF 22/249 reads (9%) | called by muse, mutect2
- PAQR4 | c.*1440A>G | 3'UTR (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
